Gene-level copy-number profile of tumor specimen TCGA-55-1595-01A from TCGA case TCGA-55-1595, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-55-1595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b24116c0-ab22-4e93-88e9-4690878bd239.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-1595-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1416b955-8ca8-4d4f-9534-52aa203f0ca1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,488; copy number 2: 13,596; copy number 3: 18,201; copy number 4: 11,690; copy number 5: 10,288; copy number 6: 2,615; copy number 7: 969; copy number 9: 248; copy number 10: 150; copy number 13: 15; copy number 16: 11; copy number 18: 181; copy number 20: 99; copy number 21: 137; copy number 26: 107; copy number 27: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-1595-01A-01D-0944-01): tumor purity 0.52, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,941 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:46,096,004–47,042,350, 18 genes, copy number 7: AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr7:15,736,373–17,346,152, 25 genes, copy number 7: AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP.
- chr7:17,373,201–17,373,326, 1 gene, copy number 7: SNORA63.
- chr11:66,389,609–69,926,813, 150 genes, copy number 10 (broad region; genes not listed).
- chr14:28,264,390–39,432,500, 205 genes, copy number 18–27 (broad region; genes not listed).
- chr17:47,200,446–83,095,122, 1,129 genes, copy number 7–9 (broad region; genes not listed).
- chr18:21,854,640–49,048,474, 367 genes, copy number 13–26 (broad region; genes not listed).
- chr18:49,049,687–49,126,479, 2 genes, copy number 26: MIR4744, AC016866.2.
- chr20:58,218,495–59,847,711, 44 genes, copy number 9 (within-gene range 6–9): ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1.

Autosomal genes at a single copy (total copy number 1): 737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
